Somatic mutation profile of tumor specimen C3L-09966-01 (aliquot CPT0516410006) from CPTAC case C3L-09966, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 85.2 years (31,122 days).
Specimen C3L-09966-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pylorus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa7e9f7c-aaee-490f-9791-86112d1f15ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09966-31 (Blood Derived Normal), aliquot CPT0516470002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dde44575-b336-4d4f-b4a1-21ada48ce815

The open-access MAF lists 238 somatic variants for this specimen: 173 protein-altering or splice-affecting, 53 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 156, Silent 53, Intron 8, Nonsense Mutation 7, Frame Shift Del 3, Splice Region 2, In Frame Del 2, Frame Shift Ins 2, 3'Flank 1, In Frame Ins 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3472A>T p.R1158* | Nonsense Mutation (SNP) | VAF 47/193 reads (24%) | catalogued as rs587779790, COSV57361782; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AAR2 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 34/464 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs766202428, COSV57924399; called by muse, mutect2
- ADAMTS16 | c.2276A>C p.N759T | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV56997474, COSV99939882; called by muse, mutect2, varscan2
- AHNAK | c.17291C>G p.P5764R | Missense Mutation (SNP) | VAF 33/380 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV57211426; called by muse, mutect2
- ASTN1 | c.1630T>G p.L544V | Missense Mutation (SNP) | VAF 55/352 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56090222; called by muse, mutect2, varscan2
- BCL9 | c.1807C>T p.R603* | Nonsense Mutation (SNP) | VAF 68/442 reads (15%) | catalogued as rs781914711; called by muse, mutect2, varscan2
- CALB2 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 38/352 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); catalogued as rs1186830523; called by muse, mutect2
- CALCR | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 31/202 reads (15%) | catalogued as rs1046608937; called by muse, mutect2, varscan2
- CASS4 | c.249C>A p.F83L | Missense Mutation (SNP) | VAF 56/804 reads (7%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV64385614; called by muse, mutect2
- CCDC184 | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 49/671 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1180231683, COSV57252483; called by muse, mutect2
- CDH11 | c.1580T>G p.F527C | Missense Mutation (SNP) | VAF 33/342 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV51750134; called by muse, mutect2
- CELSR2 | c.4327G>A p.V1443M | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs976219081, COSV54767935; called by muse, mutect2
- CFAP65 | c.5435C>T p.A1812V | Missense Mutation (SNP) | VAF 89/462 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs567905966; called by muse, mutect2, varscan2
- CNTNAP4 | c.1924A>C p.T642P | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV56666867; called by muse, mutect2
- CUBN | c.5323C>T p.R1775W | Missense Mutation (SNP) | VAF 71/317 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs1276708; called by muse, mutect2, varscan2
- DACH1 | c.1534C>T p.R512C (on ENST00000619232 / NM_001366712.1; = p.R460C on NM_080759.6) | Missense Mutation (SNP) | VAF 56/575 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.067); catalogued as rs1360283264, COSV57492480; called by muse, mutect2
- ETFB | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 53/540 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs140614695; called by muse, mutect2
- FAM155B | c.1115A>C p.K372T | Missense Mutation (SNP) | VAF 61/519 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.067); catalogued as COSV52935094; called by muse, mutect2, varscan2
- FAM171A2 | c.1748G>A p.R583H | Missense Mutation (SNP) | VAF 38/376 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.891); catalogued as rs1455811397; called by muse, mutect2, varscan2
- FAT3 | c.1100C>G p.P367R | Missense Mutation (SNP) | VAF 34/374 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.195); catalogued as COSV53179609; called by muse, mutect2
- FOXR2 | c.599T>C p.L200P | Missense Mutation (SNP) | VAF 44/438 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59259080; called by muse, mutect2, varscan2
- GABRA3 | c.542A>C p.Y181S | Missense Mutation (SNP) | VAF 71/270 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64798718; called by muse, mutect2, varscan2
- GALNT14 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 77/428 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.155); catalogued as rs200973665, COSV100205702, COSV61107078; called by muse, mutect2, varscan2
- GDF9 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as rs761806089; called by muse, mutect2, varscan2
- GLYATL1 | c.736C>T p.R246* (on ENST00000317391 / NM_001354699.1; = p.R277* on NM_080661.4) | Nonsense Mutation (SNP) | VAF 74/457 reads (16%) | catalogued as rs141077035, COSV55609560; called by muse, mutect2, varscan2
- GRIA4 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 44/276 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.07); catalogued as COSV56919037; called by muse, mutect2, varscan2
- IL17RC | c.703G>C p.E235Q (on ENST00000295981 / NM_153461.4; = p.E164Q on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV55966679; called by muse, mutect2
- IMPG2 | c.2897A>C p.K966T | Missense Mutation (SNP) | VAF 46/330 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51985849; called by muse, mutect2, varscan2
- ITGB4 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 40/296 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.437); catalogued as rs762334700, COSV52321367; called by muse, mutect2, varscan2
- KDM4C | c.1909A>G p.T637A | Missense Mutation (SNP) | VAF 34/295 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149262821; called by muse, mutect2, varscan2
- LRRC14 | c.912C>T p.L304= | Splice Region (SNP) | VAF 34/371 reads (9%) | catalogued as rs1394742698; called by muse, mutect2
- LRRC31 | c.1486C>T p.R496* | Nonsense Mutation (SNP) | VAF 40/412 reads (10%) | catalogued as rs370737804; called by muse, mutect2
- MALRD1 | c.4067T>A p.I1356K | Missense Mutation (SNP) | VAF 21/326 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1414946672; called by muse, mutect2
- MAP3K14 | c.2513G>A p.R838Q | Missense Mutation (SNP) | VAF 43/548 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371995924; called by muse, mutect2
- MCMDC2 | c.1285G>T p.E429* | Nonsense Mutation (SNP) | VAF 19/226 reads (8%) | catalogued as COSV58037741; called by muse, mutect2
- MIEF2 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 49/528 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as rs376412729, COSV59902108; called by muse, mutect2
- MUC16 | c.25834G>T p.E8612* | Nonsense Mutation (SNP) | VAF 41/578 reads (7%) | catalogued as COSV101200447; called by muse, mutect2
- MYH6 | c.2018G>A p.R673H | Missense Mutation (SNP) | VAF 36/390 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1023327699, COSV62449506; called by muse, mutect2
- MYH6 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 88/387 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62453690; called by muse, mutect2, varscan2
- MYO16 | c.818T>G p.L273R | Missense Mutation (SNP) | VAF 28/322 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV51787442, COSV51819118; called by muse, mutect2
- NIBAN2 | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 19/399 reads (5%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.966); catalogued as rs1377421221, COSV64823478; called by muse, mutect2
- NLRP13 | c.1880A>C p.E627A | Missense Mutation (SNP) | VAF 22/512 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.185); catalogued as rs953923441; called by muse, mutect2
- NR0B1 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 167/487 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.355); catalogued as COSV100973467; called by muse, mutect2, varscan2
- NTN5 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 68/697 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs1183063421; called by muse, mutect2
- NTRK3 | c.1805A>G p.K602R | Missense Mutation (SNP) | VAF 40/438 reads (9%) | SIFT tolerated (0.97); PolyPhen benign (0.208); catalogued as COSV62307128, COSV62311950; called by muse, mutect2
- OR10G7 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 35/438 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs150421981; called by muse, mutect2
- OR13C5 | c.766T>G p.F256V | Missense Mutation (SNP) | VAF 17/281 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV66164562; called by muse, mutect2
- OR5F1 | c.95T>G p.L32R | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV53546632, COSV53546830; called by muse, mutect2
- OR5T1 | c.823A>G p.S275G | Missense Mutation (SNP) | VAF 37/525 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV57302939; called by muse, mutect2
- PIEZO1 | c.3416G>A p.R1139Q | Missense Mutation (SNP) | VAF 42/386 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.054); catalogued as rs747323210, COSV56339356; called by mutect2, varscan2
- PLOD2 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.811); catalogued as rs564246642; called by muse, mutect2, varscan2
- POLR2E | c.178G>A p.V60M | Missense Mutation (SNP) | VAF 40/474 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs1287704982, COSV99297635; called by muse, mutect2
- PRKCG | c.1677C>A p.D559E | Missense Mutation (SNP) | VAF 25/348 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs763956622, COSV54723401; called by muse, mutect2
- PROC | c.905T>C p.L302P | Missense Mutation (SNP) | VAF 44/376 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99300697; called by muse, mutect2, varscan2
- RBM24 | c.655G>A p.A219T (on ENST00000379052 / NM_001143942.2; = p.A174T on NM_153020.2) | Missense Mutation (SNP) | VAF 46/336 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.281); catalogued as rs761374400, COSV59002569; called by muse, mutect2, varscan2
- RFX7 | c.848C>T p.P283L (on ENST00000559447 / NM_001368074.1; = p.P380L on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs773275578; called by muse, mutect2
- SAMM50 | c.592C>G p.Q198E | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs747021327; called by mutect2, varscan2
- SLC12A1 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 48/341 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.25); catalogued as COSV100372472; called by muse, mutect2, varscan2
- SLC14A2 | c.2291G>C p.G764A | Missense Mutation (SNP) | VAF 42/474 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs746143236; called by muse, mutect2
- SLC7A13 | c.1093T>A p.F365I | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.451); catalogued as COSV52537891; called by muse, mutect2
- SMARCA4 | c.2107G>A p.A703T | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs1555771662, COSV60805411; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMCR8 | c.2423G>A p.S808N | Missense Mutation (SNP) | VAF 45/482 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1567760672, COSV68811131; called by muse, mutect2
- TPTE2 | c.1432T>G p.F478V (on ENST00000400230 / NM_199254.2; = p.F401V on NM_130785.3) | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55026975; called by muse, mutect2, varscan2
- TRIM28 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 58/698 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1181866489; called by muse, mutect2
- TSPAN14 | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs747369194; called by muse, mutect2
- TTC28 | c.5084G>A p.S1695N | Missense Mutation (SNP) | VAF 63/419 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as rs774385853; called by muse, mutect2, varscan2
- UBQLNL | c.207A>C p.Q69H | Missense Mutation (SNP) | VAF 41/485 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66493901; called by muse, mutect2
- UCN3 | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 145/657 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs200238807; called by muse, mutect2, varscan2
- USH1G | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 52/438 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs200082225, COSV58883262; called by muse, mutect2, varscan2
- USP53 | c.2717G>T p.R906I | Missense Mutation (SNP) | VAF 41/383 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as COSV56798600; called by muse, mutect2, varscan2
- XRRA1 | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 46/278 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as rs1231264775; called by muse, mutect2, varscan2
- ZFHX4 | c.3038A>C p.K1013T | Missense Mutation (SNP) | VAF 42/382 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51481418; called by muse, mutect2
- ZFPM2 | c.1346T>A p.L449H | Missense Mutation (SNP) | VAF 68/437 reads (16%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.707); catalogued as COSV65872919; called by muse, mutect2, varscan2
- ZNF584 | c.1090A>G p.T364A | Missense Mutation (SNP) | VAF 43/498 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.908); catalogued as rs375779818; called by muse, mutect2
- ZNF835 | c.1009G>A p.G337S | Missense Mutation (SNP) | VAF 60/634 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as COSV101606405; called by muse, mutect2
- ADAMTS20 | c.2874A>C p.Q958H | Missense Mutation (SNP) | VAF 31/357 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.183); called by muse, mutect2
- ANKRD12 | c.404A>G p.K135R | Missense Mutation (SNP) | VAF 32/324 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- ATP10A | c.3752C>G p.S1251C | Missense Mutation (SNP) | VAF 30/386 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.401); called by muse, mutect2
- BAX | c.21G>T p.Q7H | Missense Mutation (SNP) | VAF 28/484 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- BICRA | c.1333A>G p.K445E | Missense Mutation (SNP) | VAF 48/606 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- C16orf96 | c.898C>T p.L300F | Missense Mutation (SNP) | VAF 56/604 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.068); called by muse, mutect2
- C5 | c.2006G>C p.C669S | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2
- CABP7 | c.327G>T p.E109D | Missense Mutation (SNP) | VAF 35/346 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2
- CEP152 | c.2460C>G p.I820M | Missense Mutation (SNP) | VAF 13/386 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); called by muse, mutect2
- CFAP251 | c.1795G>C p.E599Q | Missense Mutation (SNP) | VAF 32/374 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.374); called by muse, mutect2
- CLEC11A | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 64/706 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.029); called by muse, mutect2
- COL3A1 | c.1690G>C p.G564R | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL6A5 | c.4284A>C p.G1428= | Splice Region (SNP) | VAF 20/272 reads (7%) | called by muse, mutect2
- CRYBG1 | c.749C>A p.T250N | Missense Mutation (SNP) | VAF 66/307 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- DCC | c.2207C>G p.P736R | Missense Mutation (SNP) | VAF 26/403 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DCLRE1B | c.1087C>G p.Q363E | Missense Mutation (SNP) | VAF 38/402 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- DMXL1 | c.746C>G p.A249G | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH7 | c.1977G>C p.W659C | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- DRAP1 | c.407C>A p.T136K | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); called by muse, mutect2
- ELOVL3 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.756); called by muse, mutect2
- ESPL1 | c.4757G>T p.R1586L | Missense Mutation (SNP) | VAF 27/408 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2
- EXOSC10 | c.1615A>C p.K539Q | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FASN | c.1807G>T p.A603S | Missense Mutation (SNP) | VAF 118/481 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- FAT4 | c.10654A>G p.S3552G | Missense Mutation (SNP) | VAF 22/287 reads (8%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.737); called by muse, mutect2
- FDXR | c.1462dup p.L488Pfs*29 (on ENST00000293195 / NM_024417.5; = p.L494Pfs*29 on NM_004110.6) | Frame Shift Ins (INS) | VAF 35/330 reads (11%) | called by mutect2, pindel, varscan2
- FLNA | c.3622T>G p.Y1208D | Missense Mutation (SNP) | VAF 125/542 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- FSIP2 | c.19023G>C p.L6341F | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- GAPVD1 | c.3883G>A p.A1295T (on ENST00000394104; = p.A1304T on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/344 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GBP7 | c.1481A>C p.K494T | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); called by muse, varscan2
- GC | c.295A>C p.N99H | Missense Mutation (SNP) | VAF 19/286 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); called by muse, mutect2
- GCNT2 | c.1114A>G p.T372A (on ENST00000379597 / NM_001374747.1; = p.T370A on NM_001491.3) | Missense Mutation (SNP) | VAF 30/394 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2
- IARS1 | c.507_518del p.K169_Y173delinsN | In Frame Del (DEL) | VAF 28/232 reads (12%) | called by mutect2, pindel, varscan2
- ITGB4 | c.2122C>T p.P708S | Missense Mutation (SNP) | VAF 38/297 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IVL | c.596A>G p.Q199R | Missense Mutation (SNP) | VAF 50/780 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); called by muse, mutect2
- JMJD1C | c.7376T>C p.V2459A | Missense Mutation (SNP) | VAF 24/326 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.174); called by muse, mutect2
- KCNS1 | c.808C>G p.P270A | Missense Mutation (SNP) | VAF 47/932 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.038); called by muse, mutect2
- KHDRBS2 | c.113C>A p.S38Y | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); called by muse, mutect2
- KRTAP24-1 | c.161A>G p.N54S | Missense Mutation (SNP) | VAF 20/353 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.629); called by muse, mutect2
- LCOR | c.3988G>A p.E1330K | Missense Mutation (SNP) | VAF 31/257 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- LRP12 | c.1342T>A p.C448S | Missense Mutation (SNP) | VAF 43/453 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2
- METAP1D | c.25C>G p.L9V | Missense Mutation (SNP) | VAF 26/685 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2
- METTL22 | c.913T>C p.Y305H | Missense Mutation (SNP) | VAF 36/225 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MMP9 | c.1092G>C p.E364D | Missense Mutation (SNP) | VAF 32/764 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.03); called by muse, mutect2
- MPL | c.1035del p.T346Pfs*23 | Frame Shift Del (DEL) | VAF 36/290 reads (12%) | called by mutect2, varscan2
- MUC16 | c.27530T>C p.L9177P | Missense Mutation (SNP) | VAF 30/494 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.031); called by muse, mutect2
- MUC17 | c.10076C>G p.T3359S | Missense Mutation (SNP) | VAF 37/505 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.952); called by muse, mutect2
- MYB | c.301C>G p.Q101E | Missense Mutation (SNP) | VAF 21/217 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- MYBL1 | c.1856C>T p.S619F | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2
- MYH7 | c.3874G>T p.D1292Y | Missense Mutation (SNP) | VAF 45/332 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- MYLIP | c.773C>G p.T258S | Missense Mutation (SNP) | VAF 32/428 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.039); called by muse, mutect2
- NAV1 | c.4892G>A p.S1631N | Missense Mutation (SNP) | VAF 36/323 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- NFIA | c.181C>G p.L61V | Missense Mutation (SNP) | VAF 35/345 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- NLRP8 | c.295G>T p.D99Y | Missense Mutation (SNP) | VAF 36/355 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- NPC1 | c.977C>G p.P326R | Missense Mutation (SNP) | VAF 31/343 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2
- OR12D1 | c.559T>G p.L187V | Missense Mutation (SNP) | VAF 42/369 reads (11%) | SIFT tolerated (0.36); called by muse, mutect2, varscan2
- OR2T4 | c.211T>G p.L71V | Missense Mutation (SNP) | VAF 52/346 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.027); called by mutect2, varscan2
- OR51G2 | c.460C>G p.L154V | Missense Mutation (SNP) | VAF 33/416 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.039); called by muse, mutect2
- OR5B17 | c.316G>C p.A106P | Missense Mutation (SNP) | VAF 34/328 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- PCM1 | c.5785G>A p.E1929K | Missense Mutation (SNP) | VAF 28/353 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); called by muse, mutect2
- PDSS2 | c.589G>C p.A197P | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PIEZO2 | c.3028T>C p.F1010L | Missense Mutation (SNP) | VAF 25/240 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- PKHD1L1 | c.2072C>G p.T691S | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRDM13 | c.1758_1772del p.G587_H591del | In Frame Del (DEL) | VAF 86/456 reads (19%) | called by mutect2, pindel, varscan2
- PREX1 | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 22/387 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.726); called by muse, mutect2
- RAPGEF2 | c.4282T>G p.Y1428D | Missense Mutation (SNP) | VAF 50/316 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RGL2 | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 37/536 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.478); called by muse, mutect2
- RIMS2 | c.28C>G p.R10G | Missense Mutation (SNP) | VAF 38/444 reads (9%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.01); called by muse, mutect2
- RNF43 | c.1064C>G p.A355G | Missense Mutation (SNP) | VAF 66/560 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- RPL18 | c.425C>G p.P142R | Missense Mutation (SNP) | VAF 99/367 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RPL30 | c.179_180del p.I60Rfs*8 | Frame Shift Del (DEL) | VAF 35/189 reads (19%) | called by mutect2, pindel, varscan2
- RRP9 | c.658A>C p.S220R | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- SIPA1L3 | c.1127C>A p.S376Y | Missense Mutation (SNP) | VAF 90/506 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SLC25A44 | c.121_123dup p.I41dup | In Frame Ins (INS) | VAF 55/597 reads (9%) | called by mutect2, pindel
- SLC43A1 | c.973G>C p.V325L | Missense Mutation (SNP) | VAF 32/454 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- SLC4A10 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 35/253 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC4A1AP | c.1393G>C p.D465H | Missense Mutation (SNP) | VAF 30/355 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SMG6 | c.3091G>C p.D1031H | Missense Mutation (SNP) | VAF 44/369 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SORCS3 | c.3434A>C p.K1145T | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPDL1 | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 11/217 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- SPTA1 | c.1064T>A p.I355N | Missense Mutation (SNP) | VAF 26/434 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- STAT6 | c.1353G>C p.M451I | Missense Mutation (SNP) | VAF 30/506 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- STPG4 | c.208A>G p.I70V | Missense Mutation (SNP) | VAF 97/363 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- STRC | c.4313T>G p.L1438R | Missense Mutation (SNP) | VAF 38/372 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TAL1 | c.410T>C p.L137P | Missense Mutation (SNP) | VAF 48/492 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); called by muse, mutect2
- TARDBP | c.632_636del p.F211Sfs*25 | Frame Shift Del (DEL) | VAF 46/434 reads (11%) | called by mutect2, pindel
- TP53 | c.130_131insG p.M44Sfs*8 | Frame Shift Ins (INS) | VAF 109/371 reads (29%) | called by mutect2, pindel*, varscan2
- UBR3 | c.4642C>T p.P1548S | Missense Mutation (SNP) | VAF 9/299 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); called by muse, mutect2
- UTRN | c.7134A>C p.Q2378H | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VPS18 | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 51/422 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- WDR62 | c.2782C>G p.L928V | Missense Mutation (SNP) | VAF 40/248 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- WFIKKN2 | c.689T>C p.L230P | Missense Mutation (SNP) | VAF 56/523 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- ZFHX4 | c.1478A>G p.D493G | Missense Mutation (SNP) | VAF 60/295 reads (20%) | SIFT tolerated, low confidence (0.73); PolyPhen possibly damaging (0.701); called by muse, varscan2
- ZNF19 | c.1018T>G p.F340V | Missense Mutation (SNP) | VAF 69/379 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ZNF264 | c.1168T>A p.Y390N | Missense Mutation (SNP) | VAF 84/457 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ZNF471 | c.1186A>G p.I396V | Missense Mutation (SNP) | VAF 65/345 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- ZNF865 | c.949C>G p.P317A | Missense Mutation (SNP) | VAF 40/674 reads (6%) | SIFT tolerated (0.9); called by muse, mutect2
- ZNF865 | c.1769C>G p.S590C | Missense Mutation (SNP) | VAF 57/671 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); called by muse, mutect2
- ZSCAN31 | c.94T>G p.F32V | Missense Mutation (SNP) | VAF 36/492 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.015); called by muse, mutect2
- ABCA7 | c.804G>A p.S268= | Silent (SNP) | VAF 40/319 reads (13%) | catalogued as rs372219352; called by muse, mutect2, varscan2
- ADORA2A | c.153C>T p.A51= | Silent (SNP) | VAF 53/552 reads (10%) | catalogued as rs201925342; called by muse, mutect2
- AP5Z1 | c.1761C>T p.S587= | Silent (SNP) | VAF 51/441 reads (12%) | catalogued as rs548854387, COSV62243790; called by muse, mutect2, varscan2
- AUTS2 | c.2841G>A p.P947= | Silent (SNP) | VAF 60/628 reads (10%) | catalogued as rs1481928441, COSV100720004, COSV61388061; called by muse, mutect2
- BCO1 | c.933C>T p.N311= | Silent (SNP) | VAF 36/476 reads (8%) | catalogued as rs745955105; called by muse, mutect2
- BIRC6 | c.14439C>T p.C4813= | Silent (SNP) | VAF 99/328 reads (30%) | catalogued as rs753393918; called by muse, mutect2, varscan2
- BPIFB2 | c.966C>T p.A322= | Silent (SNP) | VAF 88/667 reads (13%) | called by muse, mutect2, varscan2
- BRF1 | c.774C>T p.S258= | Silent (SNP) | VAF 33/348 reads (9%) | catalogued as rs748507409; called by muse, mutect2
- C16orf96 | c.897A>C p.S299= | Silent (SNP) | VAF 56/599 reads (9%) | called by muse, mutect2
- CAMTA2 | c.1542C>T p.I514= | Silent (SNP) | VAF 35/335 reads (10%) | catalogued as rs1018942965, COSV61834378; called by muse, mutect2, varscan2
- CIDEA | c.426C>T p.I142= | Silent (SNP) | VAF 22/386 reads (6%) | catalogued as rs781366854; called by muse, mutect2
- CNTN3 | c.1935C>T p.T645= | Silent (SNP) | VAF 21/280 reads (8%) | catalogued as rs146095571; called by muse, mutect2
- CRB2 | c.42G>T p.L14= | Silent (SNP) | VAF 36/482 reads (7%) | called by muse, mutect2
- CTR9 | c.2454T>A p.S818= | Silent (SNP) | VAF 42/332 reads (13%) | called by muse, mutect2
- CYFIP1 | c.3285C>G p.V1095= | Silent (SNP) | VAF 51/519 reads (10%) | called by muse, mutect2
- CYP2B6 | c.168G>C p.L56= | Silent (SNP) | VAF 46/197 reads (23%) | called by muse, mutect2, varscan2
- DDX47 | c.270G>A p.P90= | Silent (SNP) | VAF 37/511 reads (7%) | catalogued as rs755971771, COSV61912055; called by muse, mutect2
- DDX59 | c.717G>T p.L239= | Silent (SNP) | VAF 38/408 reads (9%) | called by muse, mutect2
- DPP3 | c.2085C>T p.G695= | Silent (SNP) | VAF 42/446 reads (9%) | called by muse, mutect2
- ENDOG | c.513C>G p.L171= | Silent (SNP) | VAF 33/366 reads (9%) | catalogued as COSV100778213, COSV63508835; called by muse, mutect2
- FOXQ1 | c.1176G>T p.P392= | Silent (SNP) | VAF 40/423 reads (9%) | called by muse, mutect2, varscan2
- GCNT2 | c.1116C>G p.T372= (on ENST00000379597 / NM_001374747.1; = p.T370= on NM_001491.3) | Silent (SNP) | VAF 30/396 reads (8%) | called by muse, mutect2
- GDF6 | c.378G>C p.T126= | Silent (SNP) | VAF 32/302 reads (11%) | catalogued as COSV54624218; called by muse, varscan2
- GJC3 | c.744C>G p.L248= | Silent (SNP) | VAF 33/324 reads (10%) | called by muse, mutect2, varscan2
- GRM6 | c.207G>A p.L69= | Silent (SNP) | VAF 50/512 reads (10%) | called by muse, mutect2
- HDGFL1 | c.375C>T p.G125= | Silent (SNP) | VAF 114/584 reads (20%) | catalogued as rs753052032; called by muse, mutect2, varscan2
- HECTD4 | c.11652C>T p.D3884= | Silent (SNP) | VAF 51/379 reads (13%) | catalogued as rs771512946, COSV66390505; called by muse, mutect2, varscan2
- HMCN1 | c.16614C>T p.L5538= | Silent (SNP) | VAF 32/390 reads (8%) | catalogued as rs907510108, COSV54880990; called by muse, mutect2
- IGSF9B | c.654C>T p.V218= | Silent (SNP) | VAF 24/274 reads (9%) | catalogued as COSV100317499; called by muse, mutect2
- ITPR3 | c.7917C>T p.L2639= | Silent (SNP) | VAF 43/266 reads (16%) | called by muse, mutect2, varscan2
- KCNA3 | c.1242C>T p.S414= | Silent (SNP) | VAF 33/374 reads (9%) | catalogued as COSV63901463; called by muse, mutect2
- KCNA7 | c.1302C>T p.D434= | Silent (SNP) | VAF 126/468 reads (27%) | catalogued as rs145070146; called by muse, mutect2, varscan2
- KLF18 | c.1878C>T p.Y626= | Silent (SNP) | VAF 59/521 reads (11%) | catalogued as rs938178213; called by muse, mutect2, varscan2
- LAMB1 | c.5220C>G p.L1740= | Silent (SNP) | VAF 28/241 reads (12%) | called by muse, mutect2, varscan2
- MED1 | c.4632G>A p.L1544= | Silent (SNP) | VAF 39/654 reads (6%) | called by muse, mutect2
- MNDA | c.610A>C p.R204= | Silent (SNP) | VAF 37/430 reads (9%) | catalogued as COSV63741058; called by muse, mutect2
- MUC5B | c.5013G>T p.T1671= | Silent (SNP) | VAF 50/676 reads (7%) | catalogued as COSV101500866; called by muse, mutect2
- MYT1 | c.1770C>T p.F590= | Silent (SNP) | VAF 70/964 reads (7%) | catalogued as rs772557307; called by muse, mutect2
- NPTX2 | c.234C>T p.G78= | Silent (SNP) | VAF 106/573 reads (18%) | called by muse, mutect2, varscan2
- NRXN3 | c.195C>A p.L65= | Silent (SNP) | VAF 41/389 reads (11%) | called by muse, mutect2, varscan2
- OR11H1 | c.528C>T p.N176= | Silent (SNP) | VAF 71/491 reads (14%) | catalogued as rs1446675323; called by muse, mutect2, varscan2
- OR4C12 | c.342A>T p.T114= | Silent (SNP) | VAF 50/361 reads (14%) | called by muse, mutect2, varscan2
- PAPOLB | c.603C>T p.S201= | Silent (SNP) | VAF 20/292 reads (7%) | catalogued as rs1361532184; called by muse, mutect2
- PCLO | c.11754A>G p.Q3918= | Silent (SNP) | VAF 25/344 reads (7%) | catalogued as COSV61615390, COSV61633767, COSV61640511; called by muse, mutect2
- SCNN1G | c.993C>T p.I331= | Silent (SNP) | VAF 40/478 reads (8%) | called by muse, mutect2
- SHANK1 | c.3510C>T p.R1170= | Silent (SNP) | VAF 79/767 reads (10%) | catalogued as COSV99522059; called by muse, mutect2
- SLC12A7 | c.1065C>T p.Y355= | Silent (SNP) | VAF 67/448 reads (15%) | called by muse, mutect2, varscan2
- SLC29A2 | c.786T>C p.L262= | Silent (SNP) | VAF 15/440 reads (3%) | called by muse, mutect2
- TAS2R42 | c.147C>T p.T49= | Silent (SNP) | VAF 48/468 reads (10%) | called by muse, mutect2
- UHRF1BP1L | c.3624G>A p.G1208= | Silent (SNP) | VAF 57/283 reads (20%) | called by muse, mutect2, varscan2
- VPS35L | c.2601G>A p.V867= | Silent (SNP) | VAF 20/308 reads (6%) | catalogued as COSV51991830; called by muse, mutect2
- ZNF865 | c.2571C>T p.F857= | Silent (SNP) | VAF 68/704 reads (10%) | called by muse, mutect2
- ZNF865 | c.2994C>T p.F998= | Silent (SNP) | VAF 60/676 reads (9%) | called by muse, mutect2
- AKT1S1 | c.-8+622T>C | Intron (SNP) | VAF 83/528 reads (16%) | called by muse, mutect2, varscan2
- ANKMY1 | c.-122+613C>T | Intron (SNP) | VAF 86/424 reads (20%) | called by muse, mutect2, varscan2
- ASIC2 | c.556-179978G>A | Intron (SNP) | VAF 32/272 reads (12%) | called by muse, mutect2, varscan2
- C2CD6 | c.1581+3322G>C | Intron (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
- CSNK1E | c.886-2045A>G | Intron (SNP) | VAF 21/328 reads (6%) | called by muse, mutect2
- DCAF13 | chr8:103415344 T>C | 5'Flank (SNP) | VAF 56/625 reads (9%) | catalogued as COSV52567093, COSV52567749, COSV52568626; called by muse, mutect2
- PRKAA1 | c.596+496G>C | Intron (SNP) | VAF 10/86 reads (12%) | catalogued as COSV57184048; called by muse, mutect2, varscan2
- PTPRU | chr1:29325740 T>G | 3'Flank (SNP) | VAF 62/512 reads (12%) | called by muse, mutect2, varscan2
- STAT5B | c.*150G>C | 3'UTR (SNP) | VAF 48/558 reads (9%) | called by muse, mutect2
- SUFU | c.1296+82G>C | Intron (SNP) | VAF 47/390 reads (12%) | called by muse, mutect2, varscan2
- TP53I11 | c.334+172T>C | Intron (SNP) | VAF 35/431 reads (8%) | called by muse, mutect2
- TRIM8 | c.-1C>T | 5'UTR (SNP) | VAF 34/190 reads (18%) | called by muse, mutect2, varscan2
